CPTAC case C3L-02747 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/10308f8f-5298-4a66-9bf9-eb6a18c1923d

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1951; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Corpus uteri; Age at diagnosis: 66.7 years (24,345 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC clinical M: MX; AJCC pathologic T: T1a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA; FIGO stage: Stage IA; Tumor grade: G2; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 1,840 days (5.0 years); Progression or recurrence: no; Days to last follow up: 1,840 days (5.0 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 0 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 2; Margin status: Uninvolved.

Follow-up (6 entries)
- Days to follow up: 355 days; Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 355 days; Disease response: Complete Response; ECOG performance status: 0.
- Days to follow up: 725 days (2.0 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 1,103 days (3.0 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 1,475 days (4.0 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 1,840 days (5.0 years); Disease response: Tumor Free; ECOG performance status: 0.

Other clinical attributes
- Weight: 73.89 kg; Height: 160.02 cm; BMI: 28.85; Hormonal contraceptive use: Never Used.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 2.3; Cigarettes per day: 5; Tobacco smoking onset year: 1970; Tobacco smoking quit year: 1979; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 9.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02747-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 34 days; Initial weight: 160 mg; Time between clamping and freezing: 23 minutes; Time between excision and freezing: 11 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02747-22: Section location: Endometrium; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3L-02747-12: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 34 days; Time between clamping and freezing: 23 minutes; Time between excision and freezing: 11 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02747-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 34 days; Method of sample procurement: Blood Draw.
